Somatic mutation profile of tumor specimen TARGET-10-PARJNR-09A (aliquot TARGET-10-PARJNR-09A-01D) from TARGET case TARGET-10-PARJNR, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.0 years (4,000 days).
Specimen TARGET-10-PARJNR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47672568-48be-44a7-bc88-bcbb2f2208dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARJNR-10A (Blood Derived Normal), aliquot TARGET-10-PARJNR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3edfa09-c8e0-451d-acef-bc0b416cab79

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Nonsense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCNB3 | c.4159G>A p.D1387N | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.001); catalogued as COSV52079616; called by muse, mutect2, varscan2
- SPINK5 | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs779491603; called by muse, mutect2, varscan2
- TRPC6 | c.2141C>T p.T714M | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.965); catalogued as rs751038195, COSV100723560; called by muse, varscan2
- COL21A1 | c.424C>T p.L142F | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- DLAT | c.1620T>A p.D540E | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- DYNC1I1 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 34/96 reads (35%) | called by muse, mutect2, varscan2
- NCOR1 | c.1186C>T p.Q396* | Nonsense Mutation (SNP) | VAF 34/46 reads (74%) | called by muse, mutect2, varscan2
- EVI5 | c.1431T>C p.S477= | Silent (SNP) | VAF 86/213 reads (40%) | called by muse, mutect2, varscan2
- RAB42 | c.87G>A p.Q29= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV100866091; called by muse, mutect2
- ARG2 | c.*706_*732del | 3'UTR (DEL) | VAF 18/56 reads (32%) | called by mutect2, pindel
